CCDI case PBBVFG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f89091d4-0fda-445f-b789-5cc362cea9c2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,795 days).

Biospecimens (3 samples)
- Sample 0DIDS0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIDS8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIDSG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
